Somatic mutation profile of tumor specimen 0DF5CZ from CCDI case PBBRUK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.5 years (3,113 days).
Specimen 0DF5CZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3367a47d-990f-492c-b75a-60fdaaf31ee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF5CY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/173aed60-f079-4f29-9c5e-74d5831cb7d0

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 3, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 366/903 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- CD99 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as rs755239485; called by muse, mutect2, varscan2
- COL11A1 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100615383, COSV99071322; called by muse, mutect2
- LANCL3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 104/886 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV66129288; called by muse, mutect2, varscan2
- MYF5 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 33/1052 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV57354345, COSV57354486, COSV57354743; called by muse, mutect2
- NCKAP5 | c.3799G>T p.G1267C | Missense Mutation (SNP) | VAF 27/714 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491196; called by muse, mutect2
- NDUFB1 | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 262/622 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs1202292476; called by muse, mutect2, varscan2
- RAG2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 130/585 reads (22%) | catalogued as COSV57556283; called by muse, mutect2, varscan2
- SIRT4 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 90/670 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177410; called by muse, mutect2, varscan2
- CCDC8 | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 110/603 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FER1L5 | c.6178G>T p.D2060Y (on ENST00000623019; = p.D2024Y on NM_001293083.2) | Missense Mutation (SNP) | VAF 48/902 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); called by muse, mutect2
- HNRNPL | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 103/577 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL11 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 124/830 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAF1 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 127/777 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RBFOX2 | c.965-2G>C p.X322_splice (on ENST00000438146 / NM_001349995.2; = p.X251_splice on NM_001031695.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/476 reads (4%) | called by muse, mutect2
- SDF2L1 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 15/478 reads (3%) | called by muse, mutect2
- SPAM1 | c.760A>C p.N254H | Missense Mutation (SNP) | VAF 89/1017 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SRRM4 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 266/953 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPAN17 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 250/689 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.880-2A>G p.X294_splice | Splice Site (SNP) | VAF 64/497 reads (13%) | called by muse, mutect2, varscan2
- ZNF275 | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 34/727 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ID3 | c.171A>G p.G57= | Silent (SNP) | VAF 67/359 reads (19%) | called by muse, mutect2, varscan2
- OR6V1 | c.408G>T p.R136= | Silent (SNP) | VAF 132/1350 reads (10%) | catalogued as rs1427009992; called by muse, mutect2
- PLEKHG3 | c.504G>A p.L168= (on ENST00000394691; = p.L224= on NM_001308147.2) | Silent (SNP) | VAF 188/986 reads (19%) | catalogued as rs766572213; called by muse, mutect2, varscan2
- SLC52A1 | c.885C>T p.G295= | Silent (SNP) | VAF 99/326 reads (30%) | catalogued as rs367746302; called by muse, mutect2, varscan2
- SUPT5H | c.3253C>T p.L1085= | Silent (SNP) | VAF 166/949 reads (17%) | called by muse, mutect2, varscan2
- FAM114A2 | c.913+85T>C | Intron (SNP) | VAF 32/157 reads (20%) | called by mutect2, varscan2
- NUP188 | c.-1G>A | 5'UTR (SNP) | VAF 88/561 reads (16%) | catalogued as rs1404973660; called by muse, mutect2, varscan2
- OPRK1 | c.*171G>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- PLCB1 | c.1888+63C>G | Intron (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- TREM1 | c.407-85C>T | Intron (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
